Somatic mutation profile of tumor specimen MP2PRT-PAPHBW-TMP1-A (aliquot MP2PRT-PAPHBW-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPHBW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,362 days).
Specimen MP2PRT-PAPHBW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bddab2b1-68a8-4377-a2a3-06801219f13c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPHBW-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPHBW-NM1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e2348db1-bcb9-47ae-96d4-afb3c2010fcb

The open-access MAF lists 13 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GOLGB1 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762664045, COSV61465794; called by muse, mutect2, varscan2
- KDM5B | c.2738G>A p.R913H | Missense Mutation (SNP) | VAF 25/779 reads (3%) | SIFT tolerated (0.05); PolyPhen benign (0.333); catalogued as rs1287571482, COSV52509787; called by muse, mutect2
- LYG1 | c.179T>C p.I60T | Missense Mutation (SNP) | VAF 139/343 reads (41%) | SIFT tolerated (0.41); PolyPhen benign (0.372); catalogued as rs1227650350; called by muse, mutect2, varscan2
- NPAS2 | c.2423G>A p.R808Q | Missense Mutation (SNP) | VAF 202/498 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.011); catalogued as rs761660915, COSV59560719; called by muse, mutect2, varscan2
- TBL1XR1 | c.1097C>G p.S366C | Missense Mutation (SNP) | VAF 12/256 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70500343; called by muse, mutect2
- AKAP12 | c.4429C>T p.P1477S | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- BCL11A | c.1378dup p.E460Gfs*78 (on ENST00000335712 / NM_001365609.1; = p.E494Gfs*78 on NM_018014.4) | Frame Shift Ins (INS) | VAF 112/641 reads (17%) | called by mutect2, pindel, varscan2
- DOCK2 | c.3614T>G p.V1205G | Missense Mutation (SNP) | VAF 26/280 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- NKAPD1 | c.551C>T p.S184L (on ENST00000280352 / NM_001082970.2; = p.S185L on NM_018195.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/513 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); called by muse, mutect2
- ZNF189 | c.589A>T p.I197F | Missense Mutation (SNP) | VAF 24/403 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- KAT5 | c.306C>T p.S102= | Silent (SNP) | VAF 32/399 reads (8%) | catalogued as rs767056692, COSV57729400; called by muse, mutect2
- RUSC2 | c.4104G>A p.S1368= | Silent (SNP) | VAF 93/403 reads (23%) | catalogued as rs796830914, COSV63427610; called by muse, mutect2, varscan2
- SLC35F4 | c.1008G>A p.A336= (on ENST00000339762 / NM_001352015.2; = p.A300= on NM_001206920.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 85/214 reads (40%) | catalogued as rs370452519, COSV100334105; called by muse, mutect2, varscan2
